Somatic mutation profile of tumor specimen 308ad404-7079-4ff8-8232-12ee2e (aliquot 308ad404-7079-4ff8-8232-12ee2e_D6) from CPTAC case 01OV008, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 308ad404-7079-4ff8-8232-12ee2e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6013e9c-bdd7-4361-b32b-5715aa033f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3a7fef0d-d5e4-4154-adc0-dd19f5 (Blood Derived Normal), aliquot 3a7fef0d-d5e4-4154-adc0-dd19f5_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/046f1b0f-f908-44f6-bc40-8e269a291a39

The open-access MAF lists 184 somatic variants for this specimen: 123 protein-altering or splice-affecting, 36 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 36, Intron 11, Nonsense Mutation 6, In Frame Del 5, Splice Site 4, 5'UTR 4, Frame Shift Del 4, RNA 4, 3'UTR 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPAST | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 178/458 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1060502227, CD052507, CM000436, CM101456, COSV59514516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.3733G>A p.G1245S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773569562; called by muse, mutect2, varscan2
- ARL10 | c.561+5G>C | Splice Region (SNP) | VAF 45/243 reads (19%) | catalogued as rs1479096499; called by muse, mutect2, varscan2
- CBLN2 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99504091; called by muse, mutect2, varscan2
- CDCA5 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1458788417; called by muse, mutect2, varscan2
- CFAP47 | c.5012C>T p.T1671M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs372678439; called by muse, mutect2, varscan2
- CPPED1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as rs914877798; called by muse, mutect2, varscan2
- CROCC | c.2564G>C p.R855P | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs780930082; called by muse, mutect2
- DNAJA1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs780408487; called by muse, mutect2, varscan2
- DST | c.4483A>G p.I1495V (on ENST00000361203 / NM_001374722.1; = p.I1169V on NM_015548.5) | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs769885412; called by muse, mutect2, varscan2
- EIF3E | c.1063A>T p.M355L | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV55202539; called by muse, mutect2, varscan2
- ENTPD6 | c.902C>G p.S301W | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61751469; called by muse, mutect2, varscan2
- FAM110B | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.314); catalogued as rs1322055906, COSV64068922; called by muse, mutect2, varscan2
- FAM117A | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.089); catalogued as rs375320243, COSV99539569; called by muse, mutect2, varscan2
- FAM83C | c.2202_2204del p.N734del | In Frame Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs759373485; called by pindel, varscan2
- FAT3 | c.11591G>A p.R3864H | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372126226; called by muse, mutect2, varscan2
- FCAMR | c.108+1G>A p.X36_splice | Splice Site (SNP) | VAF 34/129 reads (26%) | catalogued as rs775646044; called by muse, mutect2, varscan2
- FMN2 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as COSV60432948; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305754800; called by muse, mutect2, varscan2
- GABRR3 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV72084177; called by muse, mutect2, varscan2
- GRM8 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 27/171 reads (16%) | catalogued as COSV58883196; called by mutect2, varscan2
- GTF2IRD1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1360503761, COSV56089393; called by muse, mutect2, varscan2
- HPD | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs147200520; called by muse, mutect2, varscan2
- KLF1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs368908352; called by muse, mutect2
- KLF14 | c.696C>A p.C232* | Nonsense Mutation (SNP) | VAF 64/438 reads (15%) | catalogued as COSV60589006; called by muse, mutect2, varscan2
- KMT2C | c.11069C>G p.S3690* | Nonsense Mutation (SNP) | VAF 53/252 reads (21%) | catalogued as COSV51459200; called by muse, mutect2, varscan2
- LMCD1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1263611922, COSV50087527; called by muse, mutect2, varscan2
- LRP1B | c.6499A>T p.T2167S | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV101260183; called by muse, mutect2, varscan2
- MTBP | c.2456C>T p.S819L | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59963010; called by muse, mutect2, varscan2
- MUC16 | c.25903G>C p.D8635H | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as COSV67459484; called by muse, mutect2, varscan2
- PATE1 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV59825305; called by muse, mutect2, varscan2
- PLEKHM1 | c.1878G>C p.K626N | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV69598487; called by muse, mutect2, varscan2
- PPP1R27 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 108/134 reads (81%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as rs1221882226; called by muse, mutect2, varscan2
- PPP4R1 | c.2311G>C p.E771Q (on ENST00000400556 / NM_001042388.3; = p.E754Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1164888138; called by muse, mutect2, varscan2
- RIMBP3 | c.3752C>T p.P1251L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1236566053; called by mutect2, varscan2
- SCN7A | c.1466C>G p.P489R | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV69268884; called by muse, mutect2, varscan2
- SH3D21 | c.1682C>T p.P561L (on ENST00000453908 / NM_001162530.2; = p.P450L on NM_024676.5) | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV54633366; called by muse, mutect2, varscan2
- SLC7A6 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99546601; called by muse, mutect2, varscan2
- SLX4 | c.4999C>A p.H1667N | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs746120772; called by muse, mutect2, varscan2
- SMAP2 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs141892159; called by muse, mutect2, varscan2
- TCF20 | c.5842G>A p.A1948T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs539500058, COSV59496514; called by muse, mutect2, varscan2
- TP53 | c.151del p.E51Nfs*72 | Frame Shift Del (DEL) | VAF 155/224 reads (69%) | catalogued as COSV52694020, COSV53536519; called by mutect2, pindel, varscan2
- UBC | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs762026730; called by muse, mutect2, varscan2
- WDR93 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV99175504; called by mutect2, varscan2
- YPEL5 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 77/574 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54395342; called by muse, mutect2, varscan2
- ABCB6 | c.418_441del p.I140_S147del | In Frame Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel
- ADAM23 | c.821T>A p.F274Y | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS10 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ADGRB2 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- AKAP9 | c.5749C>G p.Q1917E (on ENST00000359028; = p.Q1885E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1661T>G p.L554R | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCR | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BIRC6 | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BIRC6 | c.3866A>G p.N1289S | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BPIFB2 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC57 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- CDK18 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP295 | c.1991T>A p.I664K | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CNTNAP3 | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP3 | c.2118T>A p.N706K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); called by muse, mutect2
- COL19A1 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A6 | c.3148C>G p.P1050A | Missense Mutation (SNP) | VAF 136/201 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPS1 | c.3495_3509del p.L1166_V1170del | In Frame Del (DEL) | VAF 37/375 reads (10%) | called by mutect2, pindel
- CPT1A | c.734del p.R245Qfs*6 | Frame Shift Del (DEL) | VAF 30/257 reads (12%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CTNNA1 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DAZAP1 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DCDC2B | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EPHX3 | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 39/495 reads (8%) | called by muse, mutect2
- EXO1 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FADS6 | c.526_561del p.N176_L187del | In Frame Del (DEL) | VAF 34/171 reads (20%) | called by mutect2, pindel, varscan2
- FAM161A | c.1432G>C p.A478P | Missense Mutation (SNP) | VAF 139/414 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM83G | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- FANCI | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 107/612 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- FLG | c.6728T>C p.V2243A | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GGTLC2 | c.554T>A p.I185N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by mutect2, varscan2
- GRM4 | c.1856A>T p.K619M | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- HELZ2 | c.7518G>T p.Q2506H (on ENST00000467148 / NM_001037335.2; = p.Q1937H on NM_033405.3) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); called by muse, mutect2
- HUWE1 | c.6100T>A p.S2034T | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- IFT172 | c.1099C>G p.R367G | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IGLC3 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 62/218 reads (28%) | PolyPhen benign (0.01); called by mutect2, varscan2
- JAG1 | c.2431G>A p.G811S | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF18B | c.1069A>C p.S357R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by mutect2, varscan2
- KLHL38 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- LGALS9 | c.40-1G>A p.X14_splice | Splice Site (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- LRP6 | c.4705C>G p.P1569A | Missense Mutation (SNP) | VAF 274/435 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1A | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBLAC2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MS4A7 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MTCL1 | c.2018C>A p.P673H (on ENST00000306329 / NM_001378206.1; = p.P313H on NM_015210.4) | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR6C75 | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 249/312 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PATL2 | c.233T>A p.L78H | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX1 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 98/524 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PKD1 | c.1474T>G p.C492G | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by mutect2, varscan2
- PMS1 | c.1781C>G p.P594R | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PPOX | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 158/312 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PSMD10 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- RASSF6 | c.97A>G p.M33V (on ENST00000342081 / NM_201431.2; = p.M1? on NM_177532.5) | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPTN | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RYR1 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 98/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD11 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- SBNO1 | c.2206G>T p.E736* (on ENST00000420886; = p.E735* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 53/219 reads (24%) | called by muse, mutect2, varscan2
- SCAMP2 | c.856-1G>C p.X286_splice | Splice Site (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- SHROOM2 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SIGLEC6 | c.499T>C p.S167P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SNW1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SOX17 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A1 | c.2778_2791del p.L927Hfs*44 | Frame Shift Del (DEL) | VAF 23/240 reads (10%) | called by mutect2, pindel
- SPATA31A6 | c.2766_2779del p.L923Hfs*44 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- SPEG | c.3413C>A p.A1138D | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD15 | c.5438T>A p.V1813E | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TOGARAM1 | c.447T>G p.S149R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); called by mutect2, varscan2
- TOX3 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIO | c.9227A>T p.Q3076L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- TTN | c.11218T>A p.L3740I (on ENST00000591111; = p.L3694I on NM_003319.4) | Missense Mutation (SNP) | VAF 281/486 reads (58%) | called by muse, mutect2, varscan2
- TUBB2A | c.105T>G p.S35R | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TXLNB | c.445A>C p.M149L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- USP1 | c.396_396+7del p.X132_splice | Splice Site (DEL) | VAF 9/63 reads (14%) | called by pindel, varscan2*
- WWC1 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP2 | c.3839T>A p.L1280Q (on ENST00000628543; = p.L1455Q on NM_152381.6) | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX4 | c.5012A>G p.N1671S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF318 | c.4315C>A p.Q1439K | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF407 | c.6018_6032del p.L2008_G2012del | In Frame Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- ACSL6 | c.834C>G p.G278= (on ENST00000379240; = p.G303= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- ADAM22 | c.90C>T p.D30= | Silent (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.2292G>A p.P764= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs746640833; called by muse, mutect2, varscan2
- CAMTA1 | c.621G>A p.A207= | Silent (SNP) | VAF 46/277 reads (17%) | catalogued as rs370264033; called by muse, mutect2, varscan2
- CD163 | c.123C>A p.T41= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as rs769294403; called by muse, mutect2, varscan2
- CEP295 | c.1992A>T p.I664= | Silent (SNP) | VAF 47/285 reads (16%) | called by muse, mutect2, varscan2
- CHST8 | c.1203G>A p.Q401= | Silent (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- COPG1 | c.1483C>T p.L495= | Silent (SNP) | VAF 49/65 reads (75%) | called by muse, mutect2, varscan2
- DERA | c.69G>T p.P23= | Silent (SNP) | VAF 49/371 reads (13%) | called by muse, mutect2, varscan2
- DMXL1 | c.2619A>G p.E873= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- EVPL | c.4857G>A p.L1619= | Silent (SNP) | VAF 58/248 reads (23%) | catalogued as rs1052757657; called by muse, mutect2, varscan2
- GJA10 | c.219T>C p.S73= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.1641G>C p.A547= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- HNRNPM | c.321T>C p.A107= | Silent (SNP) | VAF 30/339 reads (9%) | called by muse, mutect2
- HTT | c.6703C>T p.L2235= | Silent (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- IFNA21 | c.507A>C p.A169= | Silent (SNP) | VAF 67/214 reads (31%) | called by muse, mutect2, varscan2
- IL16 | c.2103G>A p.R701= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as rs547915977; called by muse, mutect2, varscan2
- KIAA1210 | c.36C>T p.A12= | Silent (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- KLB | c.2646C>T p.D882= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs200449425; called by muse, mutect2, varscan2
- LAMC1 | c.4512A>G p.R1504= | Silent (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- MGAM | c.4845G>C p.L1615= | Silent (SNP) | VAF 73/172 reads (42%) | catalogued as rs1243433960; called by mutect2, varscan2
- MMP26 | c.249G>A p.G83= | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as COSV100332262, COSV56171893; called by muse, mutect2, varscan2
- MYH1 | c.2370C>G p.T790= | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as COSV56849266; called by muse, mutect2, varscan2
- MYH2 | c.5073C>A p.I1691= | Silent (SNP) | VAF 92/441 reads (21%) | catalogued as COSV55432765, COSV55434146, COSV55444155; called by muse, mutect2, varscan2
- NPBWR2 | c.252C>A p.I84= | Silent (SNP) | VAF 50/224 reads (22%) | called by mutect2, varscan2
- OR1E2 | c.819T>C p.A273= | Silent (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- PASK | c.2430C>T p.G810= | Silent (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- POLN | c.2508G>A p.L836= | Silent (SNP) | VAF 35/123 reads (28%) | called by muse, mutect2, varscan2
- RB1 | c.1554G>A p.L518= | Silent (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- SLC26A1 | c.1047C>T p.A349= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- STK35 | c.990G>A p.R330= | Silent (SNP) | VAF 53/212 reads (25%) | called by muse, mutect2, varscan2
- TEP1 | c.4527G>T p.G1509= | Silent (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- UBC | c.1986C>T p.R662= | Silent (SNP) | VAF 48/255 reads (19%) | catalogued as rs945224940; called by muse, mutect2, varscan2
- XKR5 | c.558G>A p.R186= | Silent (SNP) | VAF 69/362 reads (19%) | called by muse, mutect2, varscan2
- ZNF207 | c.111C>T p.C37= | Silent (SNP) | VAF 68/179 reads (38%) | called by muse, mutect2, varscan2
- ZNF541 | c.2358G>A p.P786= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1397162301; called by muse, mutect2, varscan2
- ADGRE4P | n.2279A>G | RNA (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- AMPH | c.1182+664C>A | Intron (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- CCL18 | c.-62C>A | 5'UTR (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- CPNE9 | c.110-10C>G | Intron (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CUL7 | c.-197C>G | 5'UTR (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- CYP4F22 | c.*36G>A | 3'UTR (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- ENTPD5 | c.218-213G>A | Intron (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446130 C>A | 3'Flank (SNP) | VAF 148/176 reads (84%) | called by muse, mutect2, varscan2
- GAD1 | c.83-43G>T | Intron (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- GON4L | chr1:155746020 C>T | 3'Flank (SNP) | VAF 5/9 reads (56%) | catalogued as rs1366622237; called by mutect2, varscan2
- HDAC11 | c.490-212G>A | Intron (SNP) | VAF 39/133 reads (29%) | called by muse, mutect2, varscan2
- IQCK | c.474+714A>G | Intron (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- LRP5L | n.199C>T | RNA (SNP) | VAF 181/335 reads (54%) | catalogued as rs781339994, COSV101292717; called by muse, mutect2, varscan2
- OSMR-AS1 | n.126+23702C>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- OTOAP1 | n.2173C>G | RNA (SNP) | VAF 64/290 reads (22%) | called by muse, varscan2
- POF1B | c.1764+24G>A | Intron (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- PRPF31 | c.*18_*30del | 3'UTR (DEL) | VAF 61/230 reads (27%) | called by mutect2, pindel, varscan2
- RBPJ | c.-102C>T | 5'UTR (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- RRN3P1 | n.2650T>G | RNA (SNP) | VAF 20/104 reads (19%) | called by muse, varscan2
- SLC29A1 | chr6:44223578 C>T | 5'Flank (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- SSR2 | c.-48C>T | 5'UTR (SNP) | VAF 28/134 reads (21%) | catalogued as COSV99828689; called by muse, mutect2, varscan2
- STARD13 | c.170-18364A>T | Intron (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- THSD4 | c.-80+15126A>G | Intron (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.552-135A>G | Intron (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- VAPB | c.*2652_*2655delinsAA | 3'UTR (DEL) | VAF 39/125 reads (31%) | called by pindel, varscan2*
